TCGA case TCGA-4K-AA1I — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Proteogenex, Inc. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e08bddcd-8ea5-4994-af6a-9fe9b7c93da4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 26 years; Year of birth: 1987; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 26.5 years (9,679 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IA; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3 days.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 3 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-4K-AA1I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 830 mg.
  Slide TCGA-4K-AA1I-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-4K-AA1I-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-4K-AA1I-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: No; Post orchi lymph node dissection: No.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS; Histologic diagnosis percent: 100.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3 days; disease-specific survival: no event (censored), 3 days; progression-free interval: no event (censored), 3 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-4K-AA1I-01A-11D-A434-01): tumor purity 0.28, ploidy 2.83, whole-genome doublings 1.
